CCG case CUPP-B5XP — CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3a6db746-eda7-41f9-bee3-4c1dee5c1d5d

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: Japan; Year of birth: 1943; Vital status: Dead; Days to death: 168 days; Year of death: 2013; Cause of death: Not Cancer Related.

Diagnoses (3)
1. Adenocarcinoma, metastatic, NOS (the primary disease): ICD-O-3 morphology code: 8140/6; ICD-10 code: C80; Tissue or organ of origin: Unknown primary site; Site of resection or biopsy: Bone, NOS; Classification of tumor: metastasis; Age at diagnosis: 69.7 years (25,444 days); Year of diagnosis: 2013; Method of diagnosis: Surgical Resection; AJCC staging edition: 8th; AJCC clinical T: TX; AJCC clinical N: N0; AJCC clinical M: M1; AJCC clinical stage: Stage IV; AJCC pathologic T: TX; AJCC pathologic N: N0; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Bone, NOS.
   Pathology details: Consistent pathology review: Yes; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Partial Response; Timepoint category: Postoperative.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Partial Response; Timepoint category: Postoperative.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Residual disease: R2; Timepoint category: First Treatment.
2. Progression of the bone (histology not recorded by GDC). Age at diagnosis: 69.9 years (25,529 days); Year of diagnosis: 2013; Days to diagnosis: 85 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease; Treatment outcome: Partial Response.
3. Progression of the adrenal gland (histology not recorded by GDC). Age at diagnosis: 69.9 years (25,529 days); Year of diagnosis: 2013; Days to diagnosis: 85 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease; Treatment outcome: Partial Response.

Follow-up (4 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 80; ECOG performance status: 1.
- Day 85 (progression): Disease response: With Tumor; Progression or recurrence: Yes; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 85 days.
- Day 85 (progression): Progression or recurrence: Yes; Progression or recurrence anatomic site: Adrenal gland, NOS; Days to progression: 85 days.
- Follow-up contact recording only the day: day 168.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 58 kg; Height: 164 cm; BMI: 21.6.

Exposures
- Tobacco smoking status: Smoker at Diagnosis; Pack years smoked: 49; Tobacco smoking onset year: 1963; Tobacco smoking quit year: 2012.

Family history
- Relative with cancer history: yes; Relationship type: Brother; Relationship primary diagnosis: Leukemia; Relationship sex at birth: male.

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample CUPP-B5XP-TTM1-A: Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide CUPP-B5XP-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 7; Percent stromal cells: 18; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 4.
